HCMI case HCM-CSHL-0516-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): first patient visit.
https://portal.gdc.cancer.gov/cases/2df05263-7905-463f-9a78-3ece600174e5

Demographics
Sex at birth: female; Days to birth: -26,645 days (73.0 years before the index date); Year of birth: 1946; Vital status: Alive.

Diagnoses (1)
1. Mucinous cystic tumor of borderline malignancy: ICD-O-3 morphology code: 8472/1; ICD-10 code: C56; Tissue or organ of origin: Ovary; Site of resection or biopsy: Overlapping lesion of female genital organs; Laterality: Right; Classification of tumor: primary; Metastasis at diagnosis: No Metastasis; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 70 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 258 days; Disease response: Complete Response; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 164 cm; BMI: 26.8.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0516-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-CSHL-0516-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
